Somatic mutation profile of tumor specimen TCGA-X9-A973-01A (aliquot TCGA-X9-A973-01A-11D-A387-09) from TCGA case TCGA-X9-A973, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 55.2 years (20,146 days).
Specimen TCGA-X9-A973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7fc414f-665b-4927-a309-22b49f00beda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X9-A973-10A (Blood Derived Normal), aliquot TCGA-X9-A973-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/157011f7-c844-4460-a501-f1865d9f4fee

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100089572; called by muse, mutect2, varscan2
- BAG6 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99277642; called by muse, mutect2
- CYP2F1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs761170962, COSV58527098; called by muse, mutect2, varscan2
- DNAH10 | c.7675G>C p.E2559Q (on ENST00000409039; = p.E2498Q on NM_207437.3) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV101292765; called by muse, mutect2, varscan2
- ENDOU | c.725A>C p.E242A (on ENST00000422538 / NM_001172439.2; = p.E201A on NM_006025.4) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as COSV99968388; called by muse, mutect2, varscan2
- GPRC6A | c.967G>T p.V323F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100114801; called by muse, mutect2, varscan2
- INSC | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1444844631, COSV101089693; called by muse, mutect2, varscan2
- KCNH5 | c.1581C>G p.I527M | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as COSV100528204; called by muse, mutect2, varscan2
- MAMLD1 | c.2136G>T p.E712D | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99476607; called by muse, mutect2, varscan2
- MEN1 | c.1268A>G p.D423G | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99581767; called by muse, mutect2, varscan2
- MFSD10 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99297019; called by muse, mutect2, varscan2
- MYH14 | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.425); catalogued as rs1471797586, COSV99224182; called by muse, varscan2
- NR0B1 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as COSV100973595; called by muse, mutect2, varscan2
- OR8K3 | c.560T>G p.L187W | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100449907; called by muse, mutect2, varscan2
- PCDHB12 | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV99507853; called by muse, mutect2, varscan2
- PDE1A | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1363883874, COSV100116433; called by muse, mutect2, varscan2
- PKD1L1 | c.1493A>G p.H498R | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs200709779, COSV99221422; called by muse, mutect2, varscan2
- RARB | c.958G>T p.E320* (on ENST00000383772 / NM_001290216.2; = p.E313* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99980367; called by muse, mutect2
- RYR1 | c.10168G>T p.G3390C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV100617047, COSV62096149; called by muse, mutect2, varscan2
- SAMHD1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99484346; called by muse, mutect2, varscan2
- SLC9A4 | c.2139G>T p.M713I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99763571; called by muse, mutect2, varscan2
- SPOCK3 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100694094; called by muse, mutect2, varscan2
- SUFU | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100883198; called by muse, mutect2, varscan2
- TRIM2 | c.1325G>T p.G442V (on ENST00000437508; = p.G469V on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV100108277, COSV58634833; called by muse, mutect2
- TRIM27 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as COSV101019463; called by muse, mutect2, varscan2
- ULBP1 | c.571A>T p.K191* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99998303; called by muse, mutect2
- CTRB1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | called by mutect2, varscan2
- TTLL5 | c.2478_2483del p.K826_N827del | In Frame Del (DEL) | VAF 35/62 reads (56%) | called by mutect2, pindel, varscan2
- CR1 | c.3678T>C p.C1226= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV100888054; called by muse, mutect2, varscan2
- CRACD | c.1239G>A p.E413= | Silent (SNP) | VAF 61/92 reads (66%) | catalogued as COSV99950036; called by muse, mutect2, varscan2
- FGFR4 | c.2352C>T p.H784= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs199622668, COSV99450960; called by muse, mutect2, varscan2
- GNAS | c.111C>T p.Y37= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs749235261, CM002268, COSV99671062; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC1 | c.3285C>T p.V1095= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99596599; called by muse, mutect2, varscan2
- OR4F6 | c.903A>T p.R301= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV100186786, COSV100187001; called by muse, mutect2, varscan2
- RBM24 | c.372G>T p.P124= (on ENST00000379052 / NM_001143942.2; = p.P79= on NM_153020.2) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV59004553; called by muse, mutect2, varscan2
- SYT16 | c.1782C>T p.S594= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs754789923, COSV101413687; called by muse, mutect2, varscan2
